Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4873, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4873-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY AND EN BLOC LYMPH NODES:

RENAL CELL CARCINOMA, CONVENTIONAL (90% CLEAR CELLS, 10% EOSINOPHILIC CELLS), FUHRMAN'S

NUCLEAR GRADE 3

TUMOR INVADES INTO THE RENAL PELVIS.

NO EXTENSION INTO THE PERINEPHRIC OR SINUS ADIPOSE TISSUE IDENTIFIED.

TUMOR MEASURES 5.0 CM IN MAXIMUM DIMENSION.

Vascular and ureteral margins, free of tumor.

Three lymph nodes, no tumor present (0/3).

GROSS DESCRIPTION

(A) RIGHT KIDNEY, EN BLOC LYMPH NODES - A nephrectomy specimen (overall 15.0 x 8.0 x 6.0 cm) including the kidney (6.5 x 5.5 x 4.5 cm) and attached ureter (8.0 cm in length and 0.5 cm in diameter).

Located in the middle anterior portion of the kidney is a well-circumscribed yellow-brown tumor with hemorrhage (5.0 x 5.0 x 5.0 cm). The tumor approaches the renal capsule, but does not extend beyond the capsule. The tumor is approaching the renal sinus and bulging into the renal pelvis. The remaining pelvis is white-tan and smooth. The remaining renal parenchyma is unremarkable.

Three unremarkable lymph nodes are identified measuring 1.5 x 0.8 x 0.6 cm, 0.9 x 0.8 x 0.5 and 0.6 x 0.5 x 0.4 cm.

INK CODE: black- Gerota's fascia.

SECTION CODE: A1, ureter and vascular resection margins; A2, tumor and Gerota's fascia inked margin; A3-A6, tumor with adjacent kidney; A7-A10, tumor with renal sinus, perpendicular to renal sinus; A11, A12, normal kidney with renal pelvis; A13, one bisected lymph node; A14, two possible lymph nodes.

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-83123

Source: NCI Genomic Data Commons file 67d15306-512d-4a12-a0ce-b90c564e7e61 (TCGA-CJ-4873.26D17131-079A-401D-99C7-CF05BBF9F48C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).